Somatic mutation profile of tumor specimen TCGA-DB-A4XF-01A (aliquot TCGA-DB-A4XF-01A-11D-A27K-08) from TCGA case TCGA-DB-A4XF, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Frontal lobe; Tumor grade: G3; Age at diagnosis: 41.2 years (15,066 days).
Specimen TCGA-DB-A4XF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ba12310-fc60-40a5-bfd2-b8c1d92614e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DB-A4XF-10A (Blood Derived Normal), aliquot TCGA-DB-A4XF-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2052a285-447c-4a25-ad5d-25c7d4d4d6d0

The open-access MAF lists 29 somatic variants for this specimen: 22 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 6, In Frame Del 3, Frame Shift Del 2, Splice Site 2, 3'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 35/86 reads (41%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 58/72 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANKLE2 | c.1593+2T>G p.X531_splice | Splice Site (SNP) | VAF 12/192 reads (6%) | catalogued as COSV100514375; called by muse, mutect2
- ARHGAP29 | c.1286C>G p.T429R | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV53117019; called by muse, mutect2, varscan2
- DEPDC4 | c.564T>G p.Y188* | Nonsense Mutation (SNP) | VAF 17/72 reads (24%) | catalogued as rs374260139; called by muse, mutect2, varscan2
- DRC7 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 79/245 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.785); catalogued as COSV61057804; called by muse, mutect2, varscan2
- LONRF2 | c.1541C>G p.P514R | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as COSV101111061, COSV66540873; called by muse, mutect2
- MAML1 | c.2596T>C p.F866L | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as COSV52988747; called by muse, mutect2, varscan2
- MYH3 | c.5491C>A p.Q1831K | Missense Mutation (SNP) | VAF 14/377 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV99878961; called by muse, mutect2
- MYORG | c.1433G>A p.R478Q | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as COSV52628350; called by muse, mutect2, varscan2
- OR4Q3 | c.299G>T p.S100I | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100057419, COSV59178310; called by muse, mutect2, varscan2
- PRMT9 | c.1361T>C p.M454T | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV59361559; called by muse, mutect2, varscan2
- SCN4B | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs771504011, COSV61252579; called by muse, mutect2, varscan2
- SRPRB | c.205_207del p.L69del | In Frame Del (DEL) | VAF 17/68 reads (25%) | catalogued as rs767427551; called by pindel, varscan2
- TANK | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1311478102, COSV52047882; called by muse, mutect2, varscan2
- TRIM55 | c.1565C>T p.A522V | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.629); catalogued as COSV52542272; called by muse, mutect2, varscan2
- VSIG4 | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 88/228 reads (39%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.955); catalogued as rs141882052, COSV66075006; called by muse, mutect2, varscan2
- ADAM32 | c.851_853del p.R284_Y285delinsH | In Frame Del (DEL) | VAF 8/78 reads (10%) | called by mutect2, pindel
- CAND1 | c.3359del p.K1120Rfs*3 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | called by mutect2, pindel, varscan2
- GIN1 | c.371_372del p.T124Sfs*22 | Frame Shift Del (DEL) | VAF 8/65 reads (12%) | called by mutect2, pindel, varscan2
- LDLRAD3 | c.49_50del p.X17_splice | Splice Site (DEL) | VAF 8/78 reads (10%) | called by pindel, varscan2
- RAB3GAP2 | c.2795_2797del p.E932del | In Frame Del (DEL) | VAF 19/59 reads (32%) | called by mutect2, pindel, varscan2
- CCIN | c.546C>A p.R182= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV58725684; called by muse, mutect2, varscan2
- CHMP1A | c.504G>A p.L168= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV53684580; called by muse, mutect2, varscan2
- EIF3I | c.90G>A p.K30= | Silent (SNP) | VAF 44/122 reads (36%) | catalogued as COSV59085738; called by muse, mutect2, varscan2
- F8 | c.1227G>A p.E409= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV64278712; called by muse, mutect2, varscan2
- HYOU1 | c.2145G>A p.K715= | Silent (SNP) | VAF 10/141 reads (7%) | catalogued as COSV101345680; called by muse, mutect2
- KRTAP10-6 | c.480C>T p.C160= | Silent (SNP) | VAF 29/349 reads (8%) | catalogued as rs1451789664, COSV100555567; called by muse, mutect2
- HLA-F | chr6:29726984 A>G | 3'Flank (SNP) | VAF 70/170 reads (41%) | catalogued as rs762043333, COSV52577312; called by muse, mutect2, varscan2
